Gene-level copy-number profile of tumor specimen TCGA-JY-A6FH-01A from TCGA case TCGA-JY-A6FH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 53.5 years (19,549 days).
Specimen TCGA-JY-A6FH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.61b1865e-ba3a-4973-99f1-33d6bf4e6bd8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A6FH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 836 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71412fd8-ec8d-49f6-842f-91103f18adf6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 25,006; copy number 2: 30,482; copy number 3: 3,684; copy number 4: 467; copy number 5: 116; copy number 9: 7; copy number 15: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A6FH-01A-11D-A33D-01): tumor purity 0.86, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:28,996,498–29,291,869, 5 genes: LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472.
- chr5:59,039,761–59,314,800, 2 genes: AC092343.1, AC008833.1.
- chr17:46,193,576–46,196,723, 1 gene: KANSL1-AS1.
- chr20:14,884,250–15,022,958, 4 genes (within-gene range 0–1): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 136 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,197,949–152,911,886, 93 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:25,701,217–25,716,715, 2 genes, copy number 5: RNU6-374P, AC022418.1.
- chr17:72,021,851–72,220,948, 3 genes, copy number 5 (within-gene range 4–5): ROCR, LINC01152, AC007461.1.
- chr17:72,072,333–72,126,416, 2 genes, copy number 5: LINC02097, SOX9.
- chr19:29,205,320–30,085,893, 27 genes, copy number 5–15: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:32,405,543–32,676,597, 7 genes, copy number 9 (within-gene range 1–9): DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1.
- chr21:34,723,807–34,784,886, 2 genes, copy number 5: LINC00160, LINC01426.

Autosomal genes at a single copy (total copy number 1): 22,632. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
